Somatic mutation profile of tumor specimen 407c600a-c0ac-41a6-8d87-fd8a3c (aliquot 407c600a-c0ac-41a6-8d87-fd8a3c_D8_1) from CPTAC case 13OV003, project CPTAC-2 (Ovary — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC.
Specimen 407c600a-c0ac-41a6-8d87-fd8a3c: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 611d8f76-4b9d-4efa-a84f-62726946bf37.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen d571ff93-f970-4fb1-939d-432b08 (Blood Derived Normal), aliquot d571ff93-f970-4fb1-939d-432b08_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c8ad0489-0c79-48e8-a9a1-436bb05c1e1f

The open-access MAF lists 39 somatic variants for this specimen: 28 protein-altering or splice-affecting, 8 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 8, Frame Shift Ins 3, Nonsense Mutation 2, Frame Shift Del 1, Splice Site 1, 3'Flank 1, 5'UTR 1, In Frame Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TCIRG1 | c.480dup p.P161Afs*66 | Frame Shift Ins (INS) | VAF 138/433 reads (32%) | catalogued as rs1554995341; ClinVar: likely pathogenic; called by mutect2, varscan2
- DNAH8 | c.1287C>A p.F429L | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59435438; called by muse, mutect2, varscan2
- ERBB4 | c.2728A>G p.I910V | Missense Mutation (SNP) | VAF 168/413 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs754195521, COSV61463153; called by muse, mutect2, varscan2
- GCGR | c.1102G>A p.V368M | Missense Mutation (SNP) | VAF 36/732 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.914); catalogued as rs771824180; called by muse, mutect2
- H1-3 | c.556G>A p.A186T | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs752873353; called by muse, mutect2, varscan2
- MAP4K4 | c.3625C>T p.R1209C (on ENST00000347699 / NM_001242559.2; = p.R1135C on NM_004834.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV56343233; called by muse, mutect2, varscan2
- MATR3 | c.1943C>A p.P648H | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); catalogued as COSV63076086; called by muse, mutect2
- OR6F1 | c.872C>T p.T291M | Missense Mutation (SNP) | VAF 91/250 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.14); catalogued as rs186143987, COSV57467500; called by muse, mutect2, varscan2
- PAPLN | c.282C>A p.F94L | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV53716505; called by muse, mutect2
- RNASEH1 | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 53/128 reads (41%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.007); catalogued as COSV59438164; called by muse, mutect2, varscan2
- RND1 | c.484G>T p.E162* | Nonsense Mutation (SNP) | VAF 24/181 reads (13%) | catalogued as COSV59045535; called by muse, mutect2, varscan2
- SMIM21 | c.210G>T p.R70S | Missense Mutation (SNP) | VAF 6/107 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.148); catalogued as COSV66895333; called by muse, mutect2
- TMEM229A | c.812C>T p.T271I | Missense Mutation (SNP) | VAF 120/323 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.157); catalogued as rs1311139879; called by muse, mutect2, varscan2
- TPST1 | c.1013C>G p.P338R | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59176060; called by muse, mutect2, varscan2
- ASCL3 | c.355C>A p.H119N | Missense Mutation (SNP) | VAF 109/268 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AXL | c.1561G>T p.E521* (on ENST00000301178 / NM_021913.5; = p.E512* on NM_001699.6) | Nonsense Mutation (SNP) | VAF 117/296 reads (40%) | called by muse, mutect2, varscan2
- BIRC6 | c.2667_2674del p.F889Lfs*5 | Frame Shift Del (DEL) | VAF 70/161 reads (43%) | called by mutect2, pindel, varscan2
- C2orf16 | c.4611G>T p.K1537N | Missense Mutation (SNP) | VAF 175/388 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- CNOT11 | c.113G>T p.G38V | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- CREBBP | c.2911dup p.R971Kfs*21 | Frame Shift Ins (INS) | VAF 154/496 reads (31%) | called by mutect2, pindel, varscan2
- EIF5A | c.350_352dup p.G117dup | In Frame Ins (INS) | VAF 113/346 reads (33%) | called by mutect2, pindel, varscan2
- GTDC1 | c.1131-1G>C p.X377_splice (on ENST00000344850 / NM_001354361.1; = p.X292_splice on NM_024659.6 and 6 other RefSeq transcripts) | Splice Site (SNP) | VAF 15/43 reads (35%) | called by muse, mutect2, varscan2
- PDCD11 | c.2911C>A p.Q971K | Missense Mutation (SNP) | VAF 155/411 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PINX1 | c.732G>T p.E244D | Missense Mutation (SNP) | VAF 130/334 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SETX | c.3127dup p.R1043Kfs*12 | Frame Shift Ins (INS) | VAF 39/126 reads (31%) | called by mutect2, pindel, varscan2
- SLC5A4 | c.633G>T p.M211I | Missense Mutation (SNP) | VAF 34/49 reads (69%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- SSX2 | c.535G>C p.E179Q | Missense Mutation (SNP) | VAF 45/256 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTF2 | c.149G>T p.C50F | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- CNGB3 | c.1695G>A p.K565= | Silent (SNP) | VAF 38/128 reads (30%) | catalogued as rs1416338159; called by muse, mutect2, varscan2
- CNOT11 | c.114C>T p.G38= | Silent (SNP) | VAF 36/82 reads (44%) | called by muse, mutect2, varscan2
- HIRA | c.2163G>A p.L721= | Silent (SNP) | VAF 63/111 reads (57%) | catalogued as COSV54277621; called by muse, mutect2, varscan2
- NR1D1 | c.432C>T p.Y144= | Silent (SNP) | VAF 48/345 reads (14%) | catalogued as rs758077603; called by muse, mutect2, varscan2
- RIMKLB | c.993G>T p.P331= | Silent (SNP) | VAF 59/457 reads (13%) | called by muse, mutect2, varscan2
- SLC47A1 | c.564C>T p.I188= | Silent (SNP) | VAF 15/296 reads (5%) | catalogued as rs914860381, COSV54500896; called by muse, mutect2
- TTN | c.90462A>G p.E30154= (on ENST00000591111; = p.E22730= on NM_003319.4) | Silent (SNP) | VAF 60/171 reads (35%) | called by muse, mutect2, varscan2
- USH2A | c.585A>G p.Q195= | Silent (SNP) | VAF 62/169 reads (37%) | called by muse, mutect2, varscan2
- CICP28 | chr7:56812145 A>T | 3'Flank (SNP) | VAF 61/110 reads (55%) | called by muse, mutect2, varscan2
- RNF213 | c.10578+19G>A | Intron (SNP) | VAF 200/580 reads (34%) | called by muse, mutect2, varscan2
- UBE2Q2 | c.-16C>T | 5'UTR (SNP) | VAF 30/84 reads (36%) | catalogued as rs779517777; called by muse, mutect2, varscan2
